Gene-level copy-number profile of tumor specimen TCGA-SC-A6LM-01A from TCGA case TCGA-SC-A6LM, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.1 years (23,400 days).
Specimen TCGA-SC-A6LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.54923bc7-8f4f-4a65-ade5-07db3f318430.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SC-A6LM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/20dd5fed-cb8e-4ab9-96b7-e7c62a4dfb2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 9,372; copy number 2: 48,179; copy number 3: 2,213; copy number 6: 4; copy number 7: 4; copy number 10: 1; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SC-A6LM-01A-11D-A34B-01): tumor purity 0.68, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,931,073, 3 genes: AL359922.2, AL359922.3, ERVFRD-3.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–89,139,458, 27 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1.
- chr10:102,402,617–102,633,535, 12 genes (within-gene range 0–1): PSD, FBXL15, CUEDC2, MIR146B, RPARP-AS1, C10orf95, MFSD13A, ACTR1A, AL121928.1, SUFU, RPL23AP58, RNU6-43P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 10 (within-gene range 2–10): AC010983.1.
- chr4:57,841,721–57,855,271, 1 gene, copy number 6: AC104790.1.
- chr5:114,576,041–114,579,970, 1 gene, copy number 6: LINC01957.
- chr6:81,724,722–81,764,503, 3 genes, copy number 7: AL078599.2, SNORA70, AL078599.1.
- chr6:115,633,540–115,643,916, 1 gene, copy number 7 (within-gene range 2–7): LINC02534.
- chr8:43,672,823–43,674,591, 2 genes, copy number 11: AC139365.2, AC139365.1.
- chr19:27,638,483–27,646,483, 2 genes, copy number 6: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 9,351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
